Gene-level copy-number profile of tumor specimen TCGA-63-A5MS-01A from TCGA case TCGA-63-A5MS, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-63-A5MS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.3d0b207b-0f7d-4678-a5a9-b2c4e6c3846a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-63-A5MS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5d572837-70eb-4241-be94-f935ec26e928

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,644; copy number 2: 28,206; copy number 3: 16,468; copy number 4: 1,888; copy number 5: 1,222; copy number 6: 701; copy number 7: 418; copy number 8: 102; copy number 11: 58; copy number 12: 5; copy number 17: 47; copy number 22: 56.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-63-A5MS-01A-11D-A26L-01): tumor purity 0.2, ploidy 3.34, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,609 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:79,185,231–80,648,861, 1 gene, copy number 5 (within-gene range 4–5): CTNNA2.
- chr2:79,547,151–85,102,694, 50 genes, copy number 5: AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080, AC016716.1, RBM7P1, LRRTM1, AC008067.1, AC012355.1, ANKRD11P1, CHMP4AP1, LINC01815, RNA5SP99, AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809, RPL37P10, RNU6-1312P, CRLF3P3, ST6GALNAC2P1, FUNDC2P2, AC106874.1, SUCLG1, DNAH6, DUXAP1, LDHAP7, TRABD2A, AC010087.1, RPL12P18, TMSB10, RPS2P17, AC022210.1, KCMF1, LINC01964, AC078974.1, LSM3P3.
- chr3:144,442,211–198,222,513, 934 genes, copy number 5–6 (broad region; genes not listed).
- chr4:52,872,982–53,366,066, 1 gene, copy number 5 (within-gene range 2–5): SCFD2.
- chr4:53,265,461–54,295,272, 19 genes, copy number 5 (within-gene range 2–5): RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13.
- chr5:58,198–45,895,970, 710 genes, copy number 5 (broad region; genes not listed).
- chr6:55,680,642–60,546,660, 37 genes, copy number 5 (within-gene range 4–5): AL590290.1, BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1, AC244258.1.
- chr11:68,612,899–71,423,423, 66 genes, copy number 6–17 (broad region; genes not listed).
- chr11:134,945,118–135,075,908, 5 genes, copy number 12: AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.
- chr12:43,718,992–48,852,842, 136 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr12:65,278,643–65,491,430, 1 gene, copy number 5 (within-gene range 3–5): MSRB3.
- chr12:65,418,731–69,331,882, 84 genes, copy number 5 (broad region; genes not listed).
- chr13:104,125,930–114,223,084, 155 genes, copy number 7–22 (broad region; genes not listed).
- chr19:36,573,070–44,726,058, 410 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,637. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
